Somatic mutation profile of tumor specimen TCGA-HZ-A8P0-01A (aliquot TCGA-HZ-A8P0-01A-11D-A36O-08) from TCGA case TCGA-HZ-A8P0, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 76.2 years (27,850 days).
Specimen TCGA-HZ-A8P0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3eccc6ab-f6bf-4022-9557-b41c246abfd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-A8P0-10A (Blood Derived Normal), aliquot TCGA-HZ-A8P0-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7fb9fdd-8737-4d83-a6ca-d7905ee6d37d

The open-access MAF lists 42 somatic variants for this specimen: 26 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 23, Silent 16, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 77/382 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.180del p.Y60* | Frame Shift Del (DEL) | VAF 56/167 reads (34%) | catalogued as rs1555735008, CD064644, CM981863, CM991149, COSV58820509, COSV58821737, COSV58821906; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BEST1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.018); catalogued as rs61747600, COSV56446076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1B | c.4840G>A p.A1614T | Missense Mutation (SNP) | VAF 90/549 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs747965799, COSV53124044, COSV99500278; called by muse, mutect2, varscan2
- CCT3 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs758436442, COSV55289576; called by muse, mutect2, varscan2
- CD207 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.552); catalogued as rs370455494, COSV101338598; called by muse, mutect2, varscan2
- DICER1 | c.1076G>A p.C359Y | Missense Mutation (SNP) | VAF 114/591 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV58615931; called by muse, mutect2, varscan2
- ESPL1 | c.4207G>A p.D1403N | Missense Mutation (SNP) | VAF 80/413 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV99229868; called by muse, mutect2, varscan2
- MYBPH | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 75/677 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.071); catalogued as rs987012139, COSV99704791; called by muse, mutect2, varscan2
- NLK | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 70/357 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV100817308; called by muse, mutect2, varscan2
- NPAS3 | c.1952A>T p.E651V (on ENST00000356141 / NM_001164749.2; = p.E619V on NM_022123.3) | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100640759; called by muse, mutect2, varscan2
- OR5A1 | c.931A>G p.K311E | Missense Mutation (SNP) | VAF 110/595 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV100118490; called by muse, mutect2, varscan2
- PLEKHG2 | c.1029G>T p.M343I | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.214); catalogued as COSV99218287; called by muse, mutect2
- POGLUT3 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 70/410 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756678069, COSV60213919; called by muse, mutect2, varscan2
- PRG4 | c.158A>C p.Y53S | Missense Mutation (SNP) | VAF 111/916 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100825970; called by muse, mutect2, varscan2
- RNF40 | c.1418A>G p.N473S | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs1376729647, COSV100222390; called by muse, mutect2, varscan2
- SKOR1 | c.1375A>T p.M459L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as rs1313980268, COSV100408705; called by muse, mutect2, varscan2
- SLCO3A1 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 74/392 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100575942; called by muse, mutect2, varscan2
- SV2A | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100975300; called by muse, mutect2, varscan2
- TNC | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 68/355 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs149181557; called by muse, mutect2, varscan2
- TTC13 | c.2324C>T p.S775L | Missense Mutation (SNP) | VAF 78/692 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs748928691, COSV100793056, COSV64170275; called by muse, mutect2, varscan2
- USH2A | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 49/433 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs375741757; called by muse, mutect2, varscan2
- WAPL | c.794A>C p.D265A | Missense Mutation (SNP) | VAF 81/342 reads (24%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.01); catalogued as COSV100077335; called by muse, mutect2, varscan2
- MUC6 | c.2712dup p.Q905Tfs*189 | Frame Shift Ins (INS) | VAF 14/109 reads (13%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.1159A>C p.N387H | Missense Mutation (SNP) | VAF 199/1055 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRTFDC1 | c.233del p.G78Vfs*9 | Frame Shift Del (DEL) | VAF 76/315 reads (24%) | called by mutect2, pindel, varscan2
- ANKDD1A | c.477G>C p.G159= | Silent (SNP) | VAF 94/509 reads (18%) | catalogued as rs760540390, COSV100132820; called by muse, mutect2, varscan2
- ARHGAP22 | c.516G>A p.A172= | Silent (SNP) | VAF 70/377 reads (19%) | catalogued as rs775636662, COSV50935452; called by muse, mutect2, varscan2
- CXCR4 | c.219G>A p.T73= | Silent (SNP) | VAF 81/446 reads (18%) | catalogued as rs909200339, COSV54017556; called by muse, mutect2, varscan2
- EMC10 | c.163C>T p.L55= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100618564; called by muse, mutect2
- FAM83H | c.381G>A p.Q127= | Silent (SNP) | VAF 41/176 reads (23%) | catalogued as rs1478434184, COSV101187088; called by muse, mutect2, varscan2
- MYBPH | c.1272C>T p.G424= | Silent (SNP) | VAF 77/687 reads (11%) | catalogued as COSV99704787; called by muse, mutect2, varscan2
- NEB | c.11574A>G p.A3858= | Silent (SNP) | VAF 130/706 reads (18%) | catalogued as COSV99428651; called by muse, mutect2, varscan2
- NLRP13 | c.2580G>A p.A860= | Silent (SNP) | VAF 34/167 reads (20%) | catalogued as rs375756102; called by muse, mutect2, varscan2
- OR2M5 | c.867C>A p.I289= | Silent (SNP) | VAF 103/746 reads (14%) | catalogued as rs1482245765, COSV100822896; called by muse, mutect2, varscan2
- PLRG1 | c.1440T>G p.A480= | Silent (SNP) | VAF 58/346 reads (17%) | catalogued as rs749350155, COSV100123283; called by muse, mutect2, varscan2
- RIMS2 | c.3342G>A p.T1114= (on ENST00000666250 / NM_001348490.2; = p.T922= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 51/247 reads (21%) | catalogued as rs1336539202, COSV51729885, COSV99165237; called by muse, mutect2, varscan2
- SLX4 | c.4485G>A p.A1495= | Silent (SNP) | VAF 165/853 reads (19%) | catalogued as rs140872903, COSV99568717; called by muse, mutect2, varscan2
- TEX37 | c.456A>G p.L152= | Silent (SNP) | VAF 67/331 reads (20%) | catalogued as rs1380923549, COSV100304703; called by muse, mutect2, varscan2
- TNFAIP3 | c.1380C>T p.A460= | Silent (SNP) | VAF 31/210 reads (15%) | catalogued as COSV99397305; called by muse, mutect2, varscan2
- TRAV3 | c.52C>T p.L18= | Silent (SNP) | VAF 71/367 reads (19%) | catalogued as rs1431048874; called by muse, mutect2, varscan2
- ZNF7 | c.750C>T p.Y250= | Silent (SNP) | VAF 88/439 reads (20%) | catalogued as rs376157890; called by muse, mutect2, varscan2
